Somatic mutation profile of tumor specimen MP2PRT-PATKKY-TMP1-B (aliquot MP2PRT-PATKKY-TMP1-B-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATKKY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,319 days).
Specimen MP2PRT-PATKKY-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e520978-e712-4fae-b739-efc1c9d8b198.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATKKY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATKKY-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/112fddf8-1ed8-429a-9517-fb053d26b7c5

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 15, Silent 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 72/327 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs968244943, COSV50461455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 91/398 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDH10 | c.2101A>T p.T701S | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV52581301; called by muse, mutect2, varscan2
- DES | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1475674849, COSV64660914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IKZF1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58788011; called by muse, mutect2, varscan2
- RBL2 | c.3383G>A p.R1128H | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1263233694; called by muse, mutect2, varscan2
- RYR2 | c.11710C>T p.R3904W | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs998659755, COSV100773660, COSV63670026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC35F1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 108/527 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs138680595, COSV64500406; called by muse, mutect2, varscan2
- TMEM47 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 101/313 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.873); catalogued as rs763483683; called by muse, mutect2, varscan2
- C2CD4B | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 166/646 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CYP3A7 | c.109G>T p.G37* | Nonsense Mutation (SNP) | VAF 65/369 reads (18%) | called by muse, mutect2, varscan2
- FREM2 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 141/505 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ILK | c.592A>G p.K198E | Missense Mutation (SNP) | VAF 92/325 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- RAD21 | c.764dup p.L255Ffs*8 | Frame Shift Ins (INS) | VAF 73/331 reads (22%) | called by mutect2, pindel, varscan2
- TOX2 | c.475G>A p.D159N (on ENST00000358131 / NM_001098798.2; = p.D108N on NM_032883.3) | Missense Mutation (SNP) | VAF 102/551 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ZBTB12 | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 228/1002 reads (23%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF217 | c.2156C>T p.T719I | Missense Mutation (SNP) | VAF 57/283 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MPPED2 | c.525C>T p.Y175= | Silent (SNP) | VAF 56/236 reads (24%) | catalogued as rs148572048; called by muse, mutect2, varscan2
- RAPGEFL1 | c.765G>A p.E255= | Silent (SNP) | VAF 53/244 reads (22%) | called by muse, mutect2, varscan2
